Surgical pathology report (de-identified scan), TCGA case TCGA-24-2020, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-2020-01A (Primary Tumor).

[page 1 of 6]
DIAGNOSIS

TCGA-24-2020

OVARIES, LEFT AND RIGHT, TAH/BSO - SEROUS PAPILLARY CARCINOMA,
FIGO GRADE III (SEE SYNOPTIC REPORT)

FALLOPIAN TUBE, LEFT AND RIGHT, TAH/BSO - METASTATIC SEROUS
PAPILLARY CARCINOMA IN MESOSALPINX WITH EXTENSIVE
VASCULAR INVASION

UTERUS, SEROSA, TAH/BSO - METASTATIC SEROUS PAPILLARY CARCINOMA

UTERUS, CERVIX, TAH/BSO - NO HISTOPATHOLOGIC ABNORMALITY

UTERUS, ENDOMETRIUM, TAH/BSO - CYSTIC ATROPHY AND INACTIVE
ENDOMETRIUM
- NO EVIDENCE OF MALIGNANCY

UTERUS, MYOMETRIUM, TAH/BSO - NO HISTOPATHOLOGIC ABNORMALITY

OMENTUM, BIOPSY - METASTATIC SEROUS PAPILLARY CARCINOMA

APPENDIX, EXCISION - METASTATIC SEROUS PAPILLARY CARCINOMA

DIAPHRAGM, BIOPSY - METASTATIC SEROUS PAPILLARY CARCINOMA

URINARY BLADDER, PERITONEUM, BIOPSY - METASTATIC SEROUS PAPILLARY
CARCINOMA

SPECIMEN(S) SUBMITTED

- Part 1: RIGHT ADNEXA
- Part 2: UTERUS, CERVIX, AND BSO
- Part 3: BLADDER PERITONEUM
- Part 4: DIAPHRAGM BIOPSY
- Part 5: OMENTUM
- Part 6: APPENDIX

[page 3 of 6]
HISTORY

The patient is a [REDACTED] with a positive inguinal lymph node which was diagnosed as metastatic poorly differentiated adenocarcinoma with papillary serous pattern [REDACTED]. Clinical diagnosis: Same. Operative procedure and findings: Examination under anesthesia, exploratory laparotomy, total abdominal hysterectomy, appendectomy, omentectomy and debulking. An intraoperative non-microscopic consultation was obtained and interpreted as: "Right adnexa: Tumor nodules present on surface of fallopian tube and ovary; sections of ovary demonstrate soft papillary pink tissue and ovary interior very suggestive of parenchymal involvement by tumor. [REDACTED] does not want frozen," by [REDACTED]

GROSS

The specimens are received in six containers of formalin, each labelled with the patient's name. The first container is labeled "R. Adnexa." It contains a mass of serosa lined soft tissue which consists of an ovary and fallopian tube. The fallopian tube measures approximately 6.0 x 1.5 cm and is lined by a brown-tan serosa with multiple irregularly shaped papillary nodules attached that are suspicious for tumor. There are also several confluent firm white tan nodules in the mesosalpinx. These are also consistent with tumor. The ovary measures 2.8 x 2.0 x 1.0 cm and is lined by a grey-tan shiny serosa. There are several white-tan firm patch like excrescences on the serosal surface which are suspicious for tumor. The cut sections through the ovary show solid white-tan friable tissue, some of which have a vague papillary type architecture. There are no cystic areas identified. Labeled RO1, section of ovary with serosal plaque; RO2 and RO3, sections through ovarian parenchyma; RT, right fallopian tube including tumor adjacent to tube and in mesosalpinx. Jar 1.

The second container is labeled "uterus, CX, LSO." It contains a uterus and cervix with left adnexa attached. The uterus measures 3.5 x 3.3 x 2.0 cm and weighs 52 grams in total. The specimen is oriented by the left adnexa and the peritoneal reflections. The uterus is lined by a grey-tan focally hemorrhagic serosa which shows a single white-tan nodule implanted on the serosa which measures approximately 0.3 x 0.2 cm. It is located on the anterior corpus. The remainder of the serosal surface is unremarkable. The left adnexa consists of fallopian tube and ovary lined by a grey-tan serosa. There is a small white-tan firm

[page 4 of 6]
GROSS (continued)

nodule implanted in the left mesosalpinx which measures approximately 0.3 cm in diameter. It is adjacent to the left fallopian tube. No other lesions are noted on the fallopian tube. The tube measures approximately 5.0 x 0.2 cm. The ovary is lined by a grey-tan glistening serosa and measures 2.3 x 1.5 x 0.8 cm. It has a slightly nodular appearance and the surface shows several flat plaque-like areas that may represent tumor. Cut section through the ovarian parenchyma shows several dense white-tan areas that are not grossly diagnostic of tumor. The ectocervix measures approximately 2.0 cm in diameter and is lined by a grey-tan shiny and focally hemorrhagic mucosa. The transformation zone is identified, but no gross lesions are noted. The uterus is opened and shows an approximately 1.0 cm in length endocervical canal which is grossly unremarkable. The endometrial cavity measures 1.0 x 0.8 x 2.5 cm in length and is lined by a grey-tan focally hemorrhagic endometrial lining. On the anterior endometrial wall there is a small slightly raised plaque-like area on the endometrial lining measuring approximately 0.3 cm in diameter and elevated approximately 0.5 cm above the otherwise smooth endometrial mucosa. No other abnormalities are noted. The myometrial wall is grey-tan, slightly trabeculated and averages approximately 0.7 cm in thickness. Labeled C1, anterior cervix; C2, posterior cervix; EM1, anterior endomyometrium (including endometrial plaque); EM2, posterior endomyometrium; S, serosal nodule; LT, left tube including nodule in mesosalpinx; LO1 and LO2, left ovary. Jar 3.

The third container is labeled "bladder peritoneum." It contains multiple fragments of brown-tan tissue with a markedly nodular and somewhat papillary appearance. The tissue fragments measure approximately 1.0 cc in aggregate volume. Labeled R. Jar 0.

The fourth container is labeled "diaphragm biopsy." It contains two small fragments of white-tan firm soft tissue measuring approximately 0.3 x 0.2 x 0.2 cm. Wrapped and labeled T. Jar 0.

The fifth container is labeled "omentum." It contains a mass of brown-tan fatty tissue consistent with omental tissue measuring 14.0 x 7.0 x 2.0 cm. Sections through the mass show white-tan firm tumor infiltrating the fatty tissue. This is grossly consistent with metastatic tumor involvement. Labeled OM. Jar 3.

The sixth container is labeled "appendix." It contains an appendix which is lined by a brown-tan serosa with a fragment of mesoappendiceal fat attached. The appendix measures 5.0 x 0.5 cm

[page 5 of 6]
GROSS (continued)

in diameter and the attached fat measures approximately 5.0 x 1.5 x 1.0 cm. The surface of the appendix and fat is glistening and shows no evidence of tumor implantation. Sections through the appendix and its adjacent fat show no evidence of malignancy. Labeled U. Jar 1.

COMMENT

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

1. The HISTOLOGIC DIAGNOSIS is:
Papillary serous adenocarcinoma
2. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are:
Indeterminate
3. The FIGO GRADE of the tumor is:
III (Tumor composed of greater than 50% solid cellular nests)
4. The NUCLEAR (BRODERS') GRADE of the tumor is:
G3 (Poorly-differentiated)
5. Tumor IS identified on the ovarian surface(s).
6. Tumor DOES invade the mesovarium.
7. Tumor DOES invade the adjacent fallopian tube.
8. Tumor DOES invade the pelvic soft tissue.
9. Tumor involvement of the pelvic peritoneum is PRESENT.
10. Metastatic involvement of the EXTRAPELVIC peritoneum is PRESENT.
11. Metastatic involvement of the omentum is PRESENT.
13. Metastatic involvement of the uterine serosa is PRESENT.
14. Metastatic involvement of the endometrium is ABSENT.
15. Regional lymph node metastases are PRESENT.
18. DETAILED STAGING INFORMATION:
Based on the above information, the PRIMARY TUMOR is classified as:

TNM SCHEME
T3c

FIGO SCHEME
IIIC

DEFINITION

Macroscopic peritoneal metastasis beyond true pelvis measuring greater than 2 cm in greatest dimension, OR Regional lymph node metastasis OR Metastasis to capsule of liver.

THE REGIONAL LYMPH NODES are classified as:

[page 6 of 6]
COMMENT (continued)

N1 (Nodes contain metastatic tumor)

THE STATUS OF DISTANT TUMOR SITES is classified as:

MX (Status cannot be assessed)

19. The FINAL AJCC/FIGO STAGE IS:

AJCC SCHEME

FIGO SCHEME

X

Insufficient data to assign stage

{End of Report}

Source: NCI Genomic Data Commons file 8245bf21-e829-4dfc-ba3c-2cfe183e57f0 (TCGA-24-2020.4F529D42-ACB0-4C02-BD0F-D4A650655DF8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).